Gene-level copy-number profile of tumor specimen TCGA-24-1428-01A from TCGA case TCGA-24-1428, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 50.1 years (18,306 days).
Specimen TCGA-24-1428-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.563f35f6-fdff-45dd-b1d1-da2622820adc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1428-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5cc83d02-1e79-4ff1-802c-0ab546c0968f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 424; copy number 2: 22,953; copy number 3: 12,863; copy number 4: 16,664; copy number 5: 2,063; copy number 6: 3,645; copy number 7: 974; copy number 8: 133; copy number 9: 85; copy number 10: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1428-01A-01D-0472-01): tumor purity 0.82, ploidy 3.3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:235,882,362–236,037,311, 2 genes: TMSB10P1, RNU7-127P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,899 genes in 42 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–19,485,539, 634 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:153,203,430–153,423,222, 13 genes, copy number 5: LELP1, PRR9, AL161636.2, LORICRIN, PGLYRP3, PGLYRP4, RNU6-160P, S100A9, S100A12, LAPTM4BP1, S100A8, S100A15A, S100A7A.
- chr1:199,371,877–201,332,993, 36 genes, copy number 6: RPL23AP16, AC099335.1, AL596266.1, AL445687.1, RNU6-778P, AL445687.2, RNU6-716P, RNU6-609P, NR5A2, RNU6-570P, AC096633.1, CCNQP1, LINC00862, AC097065.2, AC097065.1, AC104461.1, ZNF281, AL359834.1, KIF14, DDX59, DDX59-AS1, CAMSAP2, RPL34P6, GPR25, INAVA, MROH3P, RNU6-704P, KIF21B, AL358473.1, AL358473.2, CACNA1S, ASCL5, TMEM9, IGFN1, AC103925.1, PKP1.
- chr2:38,814–2,331,664, 41 genes, copy number 5: FAM110C, AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865, AC105393.2, AC105393.1, LINC01874, AC093326.2, LINC01875, AC093326.1, TMEM18, TMEM18-DT, AC092159.3, AC092159.2, AC092159.1, AC116609.3, AC116609.2, AC116609.1, LINC01115, LINC01939, AC113607.1, SNTG2-AS1, SNTG2, AC114808.1, AC114808.2, AC108462.1, AC105450.1, TPO, AC141930.1, AC141930.2, AC144450.1, PXDN, MYT1L, AC093390.2, AC093390.1, MYT1L-AS1.
- chr2:103,855,829–107,407,329, 69 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:11,745–6,736,750, 62 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr3:70,959,226–71,754,229, 1 gene, copy number 6 (within-gene range 4–6): AC097634.4.
- chr3:71,541,970–81,761,645, 119 genes, copy number 6 (broad region; genes not listed).
- chr3:100,609,601–102,479,841, 37 genes, copy number 5 (within-gene range 4–5): ADGRG7, AC069223.1, GMFBP1, TFG, ABI3BP, AC080014.1, RNU6-865P, ACTR3P3, IMPG2, SENP7, ZNF90P1, AC110994.1, AC110994.2, Y_RNA, FAM172BP, TRMT10C, PCNP, AC073861.1, AC084198.1, RNU6-1256P, Y_RNA, Y_RNA, ZBTB11, RNY1P12, ZBTB11-AS1, RPL24, AC084198.2, PDCL3P4, CEP97, NXPE3, AC020651.1, NFKBIZ, AC020651.2, LINC02085, Y_RNA, AC106712.1, ZPLD1.
- chr3:115,802,363–117,139,389, 1 gene, copy number 5 (within-gene range 4–5): LSAMP.
- chr3:116,360,024–122,518,172, 108 genes, copy number 5 (broad region; genes not listed).
- chr3:155,870,650–155,944,020, 1 gene, copy number 7 (within-gene range 4–7): GMPS.
- chr3:155,987,304–198,222,513, 746 genes, copy number 6–7 (broad region; genes not listed).
- chr4:49,096–10,268,231, 300 genes, copy number 5 (broad region; genes not listed).
- chr4:63,350,114–76,148,444, 233 genes, copy number 6 (broad region; genes not listed).
- chr5:58,198–42,924,535, 661 genes, copy number 5–6 (broad region; genes not listed).
- chr5:50,396,192–50,860,020, 6 genes, copy number 6: EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1.
- chr5:51,055,353–51,101,643, 2 genes, copy number 6: RNU6-480P, AC091834.1.
- chr5:52,787,916–52,804,044, 1 gene, copy number 6: PELO.
- chr5:52,930,606–53,094,779, 3 genes, copy number 6 (within-gene range 2–6): AC025180.1, ITGA2, AC008966.3.
- chr5:155,845,437–174,850,725, 266 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:66,087,761–68,724,048, 58 genes, copy number 5 (within-gene range 4–5): AC068533.4, CRCP, AC068533.3, TPST1, RNU6-313P, LINC00174, GTF2IP9, SKP1P1, AC008267.2, AC008267.4, AC008267.7, AC008267.5, AC008267.6, GS1-124K5.4, AC008267.1, AC008267.3, AC006001.3, AC006001.4, SAPCD2P3, AC006001.1, RPL35P5, KCTD7, AC027644.4, AC006001.2, RABGEF1, AC027644.3, AC027644.2, GTF2IRD1P1, AC027644.1, GTF2IP23, RNU6-1254P, LINC02604, AC073335.1, Metazoa_SRP, TMEM248, RN7SL43P, SBDS, TYW1, AC073089.1, MIR4650-1, SPDYE21, PMS2P4, Y_RNA, STAG3L4, AC006480.1, AC006480.2, MTATP6P21, MTCO3P41, AC005482.1, AC092648.1, AC092637.1, AC006013.1, MTCO1P57, AC093655.1, AC093655.2, MTND4P3, AC004910.1, RNA5SP231.
- chr7:112,328,189–134,579,875, 359 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:104,981,164–145,066,685, 590 genes, copy number 6–9 (broad region; genes not listed).
- chr9:33,730,345–36,171,334, 130 genes, copy number 6 (broad region; genes not listed).
- chr9:37,878,116–38,662,717, 25 genes, copy number 6: PAICSP1, SLC25A51, TMX2P1, SHB, RNU7-124P, U8, AL135785.1, ALDH1B1, IGFBPL1, AL390726.5, ARMC8P1, TCEA1P3, GAS2L1P1, VN1R48P, AL390726.1, FAM220BP, AL390726.4, FAM95C, AL390726.3, AL390726.2, SNX18P3, ANKRD18A, FAM201A, YWHABP1, AL591543.1.
- chr11:48,512,273–56,820,516, 193 genes, copy number 5 (broad region; genes not listed).
- chr11:69,909,184–115,951,491, 925 genes, copy number 6–8 (broad region; genes not listed).
- chr15:71,096,952–71,783,383, 1 gene, copy number 8 (within-gene range 4–8): THSD4.
- chr15:71,547,280–73,305,205, 44 genes, copy number 6–8 (within-gene range 2–8): AC108861.1, NR2E3, AC104938.1, MYO9A, RNA5SP399, AC022872.1, EIF5A2P1, RNU2-65P, SENP8, AC020779.1, AC020779.2, GRAMD2A, PKM, PARP6, AC009690.3, AC009690.2, CELF6, AC009690.1, HEXA, HEXA-AS1, RPL12P35, TMEM202, TMEM202-AS1, PHBP20, AC079322.1, ARIH1, MIR630, AC100827.3, AC100827.5, AC100827.2, LINC02259, AC100827.4, AC100827.1, GOLGA6B, RN7SL853P, HIGD2B, AC009712.1, BBS4, ADPGK, ADPGK-AS1, AC103874.1, NPM1P42, NEO1, NPM1P43.
- chr15:89,305,198–101,933,350, 316 genes, copy number 5 (broad region; genes not listed).
- chr16:74,667,506–75,861,157, 47 genes, copy number 5: TMPOP2, MLKL, FA2H, AC009132.1, WDR59, ZNRF1, AC099508.1, LDHD, AC099508.2, ZFP1, AC009078.1, CTRB2, CTRB1, AC009078.2, BCAR1, AC009078.3, RNU6-758P, CFDP1, AC009054.1, AC009054.2, AC009163.2, AC009163.5, AC009163.7, TMEM170A, AC009163.4, CHST6, AC009163.1, AC009163.6, TMEM231P1, AC009163.3, CHST5, TMEM231, AC025287.1, AC025287.2, GABARAPL2, AC025287.3, ADAT1, KARS1, AC025287.5, TERF2IP, AC025287.4, DUXB, RN7SL520P, ATP5PBP7, CPHXL, AC105430.1, RNA5SP430.
- chr17:142,789–6,080,792, 250 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr18:47,390–5,989,369, 121 genes, copy number 6–8 (broad region; genes not listed).
- chr18:5,956,101–5,960,785, 1 gene, copy number 6: AP001021.2.
- chr19:35,040,506–39,813,555, 271 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr19:55,158,939–58,327,248, 208 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr21:15,050,189–15,696,581, 11 genes, copy number 6: AF127577.6, AF127577.5, AF222684.1, AF222685.1, AF130248.1, AF246928.1, AJ009632.2, CYCSP42, AJ009632.1, RNU6-1326P, RAD23BP3.
- chr21:15,744,004–15,745,080, 1 gene, copy number 6: RBPMSLP.
- chr21:33,229,901–33,359,864, 6 genes, copy number 5 (within-gene range 3–5): IFNAR2, AP000295.1, IL10RB-DT, IL10RB, IFNAR1, USF1P1.

Autosomal genes at a single copy (total copy number 1): 424. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
